Gene-level copy-number profile of tumor specimen TCGA-GU-A767-01A from TCGA case TCGA-GU-A767, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.4 years (29,739 days).
Specimen TCGA-GU-A767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6bc582f4-2c17-454d-8028-b81790793d9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-A767-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/049e34ee-4f68-4dbd-ad60-d6f8bad2f64f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 668; copy number 2: 9,103; copy number 3: 14,708; copy number 4: 26,779; copy number 5: 5,150; copy number 6: 1,561; copy number 7: 1,028; copy number 8: 310; copy number 9: 227; copy number 10: 31; copy number 11: 98; copy number 12: 24; copy number 14: 25; copy number 16: 12; copy number 17: 27; copy number 19: 17; copy number 23: 9; copy number 24: 9; copy number 34: 11; copy number 43: 12; copy number 49: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-A767-01A-11D-A32A-01): tumor purity 0.3, ploidy 4.03, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 473 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,646,113–99,842,761, 6 genes, copy number 49: PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1.
- chr1:161,039,251–162,370,475, 61 genes, copy number 11–17 (within-gene range 4–17) (broad region; genes not listed).
- chr1:164,555,584–164,980,137, 9 genes, copy number 19 (within-gene range 5–19): PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr2:123,421,486–123,444,445, 2 genes, copy number 19: AC073409.2, AC073409.1.
- chr2:157,379,724–158,236,169, 14 genes, copy number 10–16: FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1.
- chr2:159,318,979–160,493,807, 20 genes, copy number 9 (within-gene range 5–9): BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1, ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785.
- chr6:18,155,329–23,404,132, 56 genes, copy number 9–43 (within-gene range 4–43): KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1.
- chr7:16,916,359–17,346,152, 1 gene, copy number 10 (within-gene range 3–10): AHR.
- chr7:16,970,320–19,146,253, 24 genes, copy number 10 (within-gene range 3–10): AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L.
- chr7:30,496,621–31,708,455, 25 genes, copy number 9: GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1, AC006466.1, AC006398.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1, PPP1R17.
- chr13:37,481,467–39,603,528, 25 genes, copy number 14–16 (within-gene range 7–16): LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571, UFM1, AL356863.1, LINC00437, LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6.
- chr19:36,445,119–41,096,195, 230 genes, copy number 9–19 (within-gene range 7–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
